Somatic mutation profile of tumor specimen a7d58d61-5049-488f-9d0a-0a4411 (aliquot a7d58d61-5049-488f-9d0a-0a4411_D6_1) from CPTAC case 11BR016, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 30.9 years (11,284 days).
Specimen a7d58d61-5049-488f-9d0a-0a4411: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f012c300-b42d-4533-808b-0701199f91f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 97a6122a-7d33-49bb-96fb-4ab468 (Blood Derived Normal), aliquot 97a6122a-7d33-49bb-96fb-4ab468_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bb6e967-ff08-49a1-a89d-c9690eacb36f

The open-access MAF lists 79 somatic variants for this specimen: 63 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 11, Nonsense Mutation 7, Frame Shift Del 6, Intron 2, Splice Site 1, In Frame Ins 1, Splice Region 1, 5'Flank 1, RNA 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 156/460 reads (34%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALDH16A1 | c.581G>C p.C194S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); catalogued as COSV99512664; called by muse, mutect2, varscan2
- AMER3 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.196); catalogued as rs778968534; called by muse, mutect2, varscan2
- ANK3 | c.6532C>T p.P2178S | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55049573; called by muse, mutect2, varscan2
- BRINP1 | c.1301A>G p.N434S | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs1378670806; called by muse, mutect2, varscan2
- FLG | c.3904T>G p.S1302A | Missense Mutation (SNP) | VAF 136/863 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV64239859; called by muse, mutect2, varscan2
- FMNL1 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs759257998; called by muse, mutect2, varscan2
- FRG2B | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 54/380 reads (14%) | catalogued as rs755493254; called by muse, varscan2
- GOLGA4 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774482115, COSV62710222, COSV62710437; called by muse, mutect2, varscan2
- N4BP1 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs767743824; called by muse, mutect2, varscan2
- NPR1 | c.2471C>G p.A824G | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV64117295; called by muse, mutect2, varscan2
- OR2M7 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 114/638 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV58740190; called by muse, mutect2, varscan2
- OR2W3 | c.662T>A p.I221N | Missense Mutation (SNP) | VAF 74/433 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100831656; called by muse, mutect2, varscan2
- OSBPL10 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV101159960; called by muse, mutect2, varscan2
- PAPPA2 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs770493671, COSV100866600, COSV62776460; called by muse, mutect2, varscan2
- PRDM8 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 68/319 reads (21%) | catalogued as rs375338780; called by muse, mutect2, varscan2
- RELN | c.7465G>A p.G2489R | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100634657; called by muse, mutect2, varscan2
- SLC2A5 | c.1174+1G>C p.X392_splice | Splice Site (SNP) | VAF 70/164 reads (43%) | catalogued as COSV101072663; called by muse, mutect2, varscan2
- SYT9 | c.783G>C p.K261N | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59614748; called by muse, mutect2, varscan2
- TAL1 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs1476559742; called by muse, mutect2, varscan2
- TEKT4 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202183695, COSV54627674, COSV99726093; called by muse, mutect2, varscan2
- TNRC6C | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV56947415; called by muse, mutect2, varscan2
- UGT1A5 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 85/449 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59396067; called by muse, mutect2, varscan2
- ABCB7 | c.2003C>G p.S668* (on ENST00000373394 / NM_001271696.3; = p.S669* on NM_004299.6) | Nonsense Mutation (SNP) | VAF 45/208 reads (22%) | called by muse, mutect2, varscan2
- ADNP | c.735_749del p.R246_Q250del | In Frame Del (DEL) | VAF 61/241 reads (25%) | called by mutect2, pindel, varscan2
- ATRNL1 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- CEP78 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP69 | c.2320C>G p.P774A | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); called by muse, mutect2
- CHST15 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CUL2 | c.54G>C p.L18F | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CYBRD1 | c.715G>T p.G239* | Nonsense Mutation (SNP) | VAF 57/271 reads (21%) | called by muse, mutect2, varscan2
- DCP1A | c.1349C>G p.A450G | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.366); called by muse, mutect2
- DLG2 | c.369A>C p.E123D (on ENST00000650630 / NM_001351274.2; = p.E86D on NM_001142699.3) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAJC5 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 95/496 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ENTPD4 | c.965T>G p.V322G | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HPX | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 75/341 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IGFBP1 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.525); called by muse, varscan2
- IGKV1D-43 | c.108_129del p.V37Lfs*12 | Frame Shift Del (DEL) | VAF 86/526 reads (16%) | called by mutect2, pindel, varscan2
- IL4R | c.1537C>G p.L513V | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- KIF21B | c.603C>G p.I201M | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- KMT2A | c.1740C>A p.D580E | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- LCE4A | c.143_144insCTGCAGCTCTGGGGGCTG p.C48_G49insCSSGGC | In Frame Ins (INS) | VAF 45/270 reads (17%) | called by mutect2, varscan2
- LHX3 | c.1100G>T p.S367I (on ENST00000371748 / NM_178138.6; = p.S372I on NM_014564.5) | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- NOTCH2 | c.6901_6907del p.L2301Pfs*3 | Frame Shift Del (DEL) | VAF 57/265 reads (22%) | called by mutect2, varscan2
- NOTCH4 | c.2137T>G p.Y713D | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OGG1 | c.771G>T p.M257I | Missense Mutation (SNP) | VAF 53/359 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- OPTN | c.1124A>G p.E375G | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PANX3 | c.254_266del p.W85Ffs*13 | Frame Shift Del (DEL) | VAF 15/142 reads (11%) | called by mutect2, pindel, varscan2
- PARP8 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- PCDHB14 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- PRAMEF12 | c.733T>C p.C245R | Missense Mutation (SNP) | VAF 57/381 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRRC2C | c.6211G>T p.V2071F (on ENST00000367742; = p.V2069F on NM_015172.4) | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.23); called by muse, mutect2
- SLC4A4 | c.2513_2516del p.L838Rfs*4 (on ENST00000264485 / NM_001098484.3; = p.L794Rfs*4 on NM_003759.4) | Frame Shift Del (DEL) | VAF 32/359 reads (9%) | called by mutect2, pindel
- SLC9C1 | c.233T>G p.L78* | Nonsense Mutation (SNP) | VAF 32/130 reads (25%) | called by muse, mutect2, varscan2
- SMARCA5 | c.1089T>C p.D363= | Splice Region (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- SRCAP | c.9428C>T p.A3143V | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBCCD1 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- UBOX5 | c.748_761del p.Q250Dfs*7 | Frame Shift Del (DEL) | VAF 71/283 reads (25%) | called by mutect2, pindel, varscan2
- UNC5C | c.11G>C p.G4A | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZIC1 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 81/389 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF208 | c.2102C>A p.A701D | Missense Mutation (SNP) | VAF 102/494 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- ZNF208 | c.1645G>A p.G549R | Missense Mutation (SNP) | VAF 81/334 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF862 | c.2320_2342del p.L774Efs*140 | Frame Shift Del (DEL) | VAF 76/366 reads (21%) | called by mutect2, pindel, varscan2
- CAVIN2 | c.657C>T p.A219= | Silent (SNP) | VAF 56/499 reads (11%) | catalogued as rs767514926, COSV58426097; called by muse, mutect2, varscan2
- CDK12 | c.1224T>A p.A408= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs764336794; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1173G>A p.Q391= | Silent (SNP) | VAF 113/325 reads (35%) | catalogued as rs1407290006; called by muse, mutect2, varscan2
- CLN8 | c.51C>T p.D17= | Silent (SNP) | VAF 74/232 reads (32%) | called by muse, mutect2, varscan2
- COL20A1 | c.255G>A p.L85= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV58915439; called by muse, mutect2, varscan2
- CYP26C1 | c.66G>A p.A22= | Silent (SNP) | VAF 51/213 reads (24%) | catalogued as rs751379382, COSV53321293; called by muse, mutect2, varscan2
- GPATCH4 | c.666T>G p.A222= | Silent (SNP) | VAF 22/163 reads (13%) | called by muse, mutect2, varscan2
- IRAG1 | c.282G>T p.G94= | Silent (SNP) | VAF 32/110 reads (29%) | called by muse, varscan2
- PANX3 | c.702C>G p.V234= | Silent (SNP) | VAF 50/280 reads (18%) | called by muse, mutect2, varscan2
- PDE3A | c.1074C>A p.T358= | Silent (SNP) | VAF 82/325 reads (25%) | catalogued as rs1457139545, COSV100761597; called by muse, mutect2, varscan2
- TOP2A | c.3231G>C p.L1077= | Silent (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- AFDN | chr6:167825726 A>G | 5'Flank (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- CLEC18A | c.*19_*20del | 3'UTR (DEL) | VAF 22/182 reads (12%) | called by mutect2, varscan2
- CPSF4 | c.104-1651A>T | Intron (SNP) | VAF 34/410 reads (8%) | called by muse, mutect2
- NOP53 | c.1296+114G>T | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.662G>A | RNA (SNP) | VAF 3/23 reads (13%) | catalogued as rs1213315810; called by muse, mutect2
